CCDI case PBCLTL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c837ac69-7cf3-4cdc-901b-145108123da2

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 5.3 years (1,921 days).

Biospecimens (3 samples)
- Sample 0DUUP5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUUPO: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DUUQ2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
